Gene-level copy-number profile of tumor specimen C3L-04080-02 (profiled together with C3L-04080-03) from CPTAC case C3L-04080, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 70.8 years (25,862 days).
Specimen C3L-04080-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file f7649dae-4100-4683-a177-a52596f4e232.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-04080-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,712 have no estimate.
https://portal.gdc.cancer.gov/files/f9c807ae-0c81-4a78-a661-0fd1dcd38a64

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 146; copy number 1: 15,217; copy number 2: 38,627; copy number 3: 4,904; copy number 4: 6; copy number 5: 3; copy number 11: 8.

Homozygous deletions (total copy number 0; autosomes only): 145 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:241,881,363–242,084,233, 7 genes (within-gene range 0–2): LINC01237, FAM240C, LINC01238, AC093642.3, AC093642.1, AC093642.6, LINC01880.
- chr9:21,135,598–30,690,272, 112 genes (broad region; genes not listed).
- chr9:37,878,116–37,904,353, 3 genes (within-gene range 0–1): PAICSP1, SLC25A51, TMX2P1.
- chr9:37,936,707–39,039,594, 23 genes (within-gene range 0–1): RNU7-124P, U8, AL135785.1, ALDH1B1, IGFBPL1, AL390726.5, ARMC8P1, TCEA1P3, GAS2L1P1, VN1R48P, AL390726.1, FAM220BP, AL390726.4, FAM95C, AL390726.3, AL390726.2, SNX18P3, ANKRD18A, FAM201A, YWHABP1, RNU6-765P, AL845311.1, VN2R3P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 11 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:52,473–71,585, 3 genes, copy number 5: OR4G4P, OR4G11P, OR4F5.
- chr1:137,682–195,411, 8 genes, copy number 11: AL627309.7, AL627309.2, AL627309.5, RNU6-1100P, AL627309.4, FO538757.1, WASH9P, MIR6859-2.

Autosomal genes at a single copy (total copy number 1): 12,366. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
